Somatic mutation profile of tumor specimen TARGET-30-PARSRJ-01A (aliquot TARGET-30-PARSRJ-01A-01D) from TARGET case TARGET-30-PARSRJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.2 years (1,905 days).
Specimen TARGET-30-PARSRJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35cbf8e7-9e0c-42f6-8b43-ced5b44f23b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARSRJ-10A (Blood Derived Normal), aliquot TARGET-30-PARSRJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/456274cc-9117-442e-afda-2bd248a86ca3

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C7orf57 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV62361630; called by muse, mutect2, varscan2
- CSNK1G2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs769685317, COSV55335835, COSV55336091; called by muse, mutect2, varscan2
- DEPTOR | c.142A>C p.K48Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV53812282; called by muse, mutect2, varscan2
- ENPP4 | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58088107; called by muse, mutect2, varscan2
- FOXA3 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV100141329, COSV56215032; called by muse, mutect2, varscan2
- HTR1B | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.774); catalogued as COSV64051069, COSV64052073; called by muse, mutect2, varscan2
- KCNH8 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV60456008, COSV60472373; called by muse, mutect2, varscan2
- PKD1L2 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1395341094, COSV61411402; called by muse, mutect2, varscan2
- RPL7 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV53581129; called by muse, mutect2, varscan2
- SEC24D | c.1977C>A p.Y659* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV54876512; called by muse, mutect2, varscan2
- TDP1 | c.1015A>T p.I339L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV59642008; called by muse, mutect2, varscan2
- IGLV2-23 | c.331T>C p.S111P | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRO | c.2922_2932del p.N974Kfs*21 | Frame Shift Del (DEL) | VAF 19/23 reads (83%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.2340G>A p.P780= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs757035620, COSV59352309; called by muse, mutect2, varscan2
- CUEDC1 | c.288C>T p.G96= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as rs762941557, COSV64225990; called by muse, mutect2, varscan2
- ROBO3 | c.85C>T p.L29= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV67299250; called by muse, mutect2, varscan2
